Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19J, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19J-06A (Metastatic).

ICD-0-3

Melanoma, NOS 8720/3 12/15/10 hr

PATIENT HISTORY:

Not given

PRE-OP DIAGNOSIS: Melanoma left ear

POST-OP DIAGNOSIS: Same

PROCEDURE: Modified radical left neck dissection

Site code: Neck, soft tissue C49.0

FINAL DIAGNOSIS:

PART 1: LEFT ANTERIOR NECK LYMPH NODE, DISSECTION -

- A. SUBMANDIBULAR SALIVARY GLAND WITH MILD CHRONIC INFLAMMATION, FREE OF TUMOR.
- B. SIX LYMPH NODES FREE OF TUMOR.

PART 2: SOFT TISSUE AND LYMPH NODES, POSTERIOR NECK LYMPH NODE, DISSECTION -

METASTATIC MALIGNANT MELANOMA IN EIGHT OUT OF TWENTY LYMPH NODES AND ADJACENT SKELETAL AND SOFT TISSUE (see comment).

COMMENT:

The largest mass is 4.5 cm: and represents tumor bearing lymph node and adjacent soft tissue and in addition, small tumor nodules are present in skeletal muscle.

HI/AA Discrepancy		☒

Source: NCI Genomic Data Commons file 29917c1d-adbd-45cd-9a12-9ae038f945ac (TCGA-ER-A19J.BEFD8A84-630A-4ED9-B223-491147223D45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).